CCDI case PBBJIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/ecba4be4-8abd-4fe2-ace9-5598cf4bb339

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.6 years (4,976 days).

Biospecimens (3 samples)
- Sample 0DA0VE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DA0VG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DA0VH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
